Somatic mutation profile of tumor specimen C3N-01346-03 (aliquot CPT0116550007) from CPTAC case C3N-01346, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G3; Age at diagnosis: 63.4 years (23,139 days).
Specimen C3N-01346-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2770732f-e9e1-4294-9f58-ea688e6c47a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01346-31 (Blood Derived Normal), aliquot CPT0116610002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bddeddf-391a-45a0-8b18-1540d8d5f219

The open-access MAF lists 64 somatic variants for this specimen: 46 protein-altering or splice-affecting, 10 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, Intron 4, Frame Shift Del 3, Nonsense Mutation 3, RNA 2, Splice Site 1, 5'UTR 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 82/230 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CACNA1F | c.4044G>A p.M1348I | Missense Mutation (SNP) | VAF 26/441 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.235); catalogued as rs782443454; called by muse, mutect2
- CNOT8 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs772806869; called by muse, mutect2, varscan2
- CSNK1D | c.886-4T>G | Splice Region (SNP) | VAF 152/495 reads (31%) | catalogued as rs1348335581; called by muse, mutect2, varscan2
- ESRRB | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 84/316 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); catalogued as COSV55062297; called by muse, mutect2, varscan2
- GAD1 | c.1591C>T p.R531* | Nonsense Mutation (SNP) | VAF 133/489 reads (27%) | catalogued as rs745595462; called by muse, mutect2, varscan2
- GRHL1 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.013); catalogued as rs774309416; called by muse, mutect2, varscan2
- IGKV1D-37 | c.327C>A p.Y109* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as rs1401427904; called by mutect2, varscan2
- IRX3 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV100315297; called by muse, mutect2, varscan2
- LRRC58 | c.706C>T p.H236Y | Missense Mutation (SNP) | VAF 82/336 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as rs770871284; called by muse, mutect2, varscan2
- MED14 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 87/292 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1379065821, COSV61356851; called by muse, mutect2, varscan2
- PEX11B | c.92C>G p.A31G | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs782229863, COSV100355220; called by muse, mutect2, varscan2
- PIK3R2 | c.1063C>G p.R355G | Missense Mutation (SNP) | VAF 57/264 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55848230; called by muse, mutect2, varscan2
- PLEC | c.835C>G p.L279V (on ENST00000322810 / NM_201380.4; = p.L169V on NM_000445.5) | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV59634419; called by muse, mutect2, varscan2
- POP1 | c.2479C>T p.R827W | Missense Mutation (SNP) | VAF 121/343 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as rs138030882; called by muse, mutect2, varscan2
- PSG8 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 98/309 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.406); catalogued as rs757599628, COSV60610340, COSV60612101; called by muse, mutect2, varscan2
- RADX | c.467G>C p.G156A | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV65318627; called by muse, mutect2, varscan2
- STK3 | c.1461G>T p.R487S | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV69222672; called by muse, mutect2, varscan2
- TMEM132B | c.3022del p.E1008Kfs*7 | Frame Shift Del (DEL) | VAF 83/347 reads (24%) | catalogued as COSV54753080; called by mutect2, pindel, varscan2
- TPO | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768830989, COSV61108451; called by muse, mutect2, varscan2
- TTC3 | c.1615G>A p.V539I | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.979); catalogued as rs1481898353; called by muse, mutect2, varscan2
- ACSM5 | c.1139C>G p.A380G | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CABLES1 | c.1858C>G p.H620D (on ENST00000256925 / NM_001100619.2; = p.H355D on NM_138375.2) | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- CDH23 | c.5903T>G p.V1968G | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- CSMD2 | c.5971A>T p.N1991Y | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DDX50 | c.1291C>G p.L431V | Missense Mutation (SNP) | VAF 72/331 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- DNMT3B | c.2321T>G p.I774R | Missense Mutation (SNP) | VAF 22/413 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- DPP10 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- FADS6 | c.1056T>G p.Y352* | Nonsense Mutation (SNP) | VAF 59/238 reads (25%) | called by muse, mutect2, varscan2
- FOCAD | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- FOS | c.683del p.P228Qfs*37 | Frame Shift Del (DEL) | VAF 77/342 reads (23%) | called by mutect2, pindel, varscan2
- FRK | c.206T>G p.L69R | Missense Mutation (SNP) | VAF 117/403 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GLRA4 | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 107/335 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- GRIN3A | c.175A>T p.T59S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- HERPUD1 | c.791G>C p.W264S | Missense Mutation (SNP) | VAF 21/444 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGF1R | c.2530C>T p.P844S | Missense Mutation (SNP) | VAF 103/277 reads (37%) | SIFT tolerated (0.98); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHG1 | c.397A>T p.T133S | Missense Mutation (SNP) | VAF 13/309 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.379); called by muse, mutect2
- KAT5 | c.241A>G p.N81D | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- LSR | c.808G>A p.A270T (on ENST00000361790; = p.A251T on NM_015925.6) | Missense Mutation (SNP) | VAF 81/252 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MAN2B1 | c.1178C>G p.S393C | Missense Mutation (SNP) | VAF 109/470 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- MTUS1 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.232); called by mutect2, varscan2
- NSUN7 | c.641+3_641+6del p.X214_splice | Splice Site (DEL) | VAF 47/208 reads (23%) | called by mutect2, pindel, varscan2
- OR10J3 | c.623_639del p.L208Pfs*15 | Frame Shift Del (DEL) | VAF 97/427 reads (23%) | called by mutect2, pindel, varscan2
- PAX8 | c.347T>C p.V116A | Missense Mutation (SNP) | VAF 96/540 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PLD2 | c.898C>G p.R300G | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, varscan2
- SUPT20HL2 | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 79/302 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.777); called by mutect2, varscan2
- BIRC3 | c.303C>T p.S101= | Silent (SNP) | VAF 105/379 reads (28%) | catalogued as rs374571638, COSV54815001; called by muse, mutect2, varscan2
- CCT8 | c.201C>T p.N67= | Silent (SNP) | VAF 38/184 reads (21%) | catalogued as rs753807581; called by muse, mutect2, varscan2
- CYP2C8 | c.618G>A p.R206= | Silent (SNP) | VAF 84/294 reads (29%) | catalogued as rs867104252, COSV64879144; called by muse, mutect2, varscan2
- ITPRID2 | c.132A>G p.T44= | Silent (SNP) | VAF 84/279 reads (30%) | called by muse, mutect2, varscan2
- KCND1 | c.249C>T p.F83= | Silent (SNP) | VAF 11/235 reads (5%) | catalogued as COSV54413379; called by muse, mutect2
- LENG8 | c.1464C>G p.T488= | Silent (SNP) | VAF 29/138 reads (21%) | catalogued as rs754485161; called by muse, mutect2
- PACS2 | c.1431C>G p.L477= | Silent (SNP) | VAF 41/150 reads (27%) | called by muse, mutect2, varscan2
- PTGER4 | c.33C>G p.S11= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV56722307; called by muse, mutect2
- VPS13B | c.8343G>C p.L2781= | Silent (SNP) | VAF 86/330 reads (26%) | catalogued as rs1204713346; called by muse, mutect2, varscan2
- ZNF875 | c.1134G>A p.A378= | Silent (SNP) | VAF 54/182 reads (30%) | catalogued as rs754110975, COSV60991544; called by muse, mutect2, varscan2
- EDA2R | c.*35G>T | 3'UTR (SNP) | VAF 22/106 reads (21%) | catalogued as rs1200688842; called by muse, mutect2, varscan2
- EPB41L1 | c.-15+725G>T | Intron (SNP) | VAF 39/156 reads (25%) | called by muse, mutect2, varscan2
- ERCC6 | c.4062+34A>C | Intron (SNP) | VAF 107/345 reads (31%) | catalogued as rs1435412800; called by muse, mutect2, varscan2
- HSDL2 | c.-39C>T | 5'UTR (SNP) | VAF 61/182 reads (34%) | catalogued as rs967074311; called by muse, mutect2, varscan2
- LINC02145 | n.435A>T | RNA (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2, varscan2
- POR | c.189-4137A>G | Intron (SNP) | VAF 33/135 reads (24%) | called by muse, mutect2, varscan2
- PRMT2 | c.654+3111A>G | Intron (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- TBC1D3P1 | n.293C>T | RNA (SNP) | VAF 46/202 reads (23%) | catalogued as rs1338858218; called by mutect2, varscan2
